Gene-level copy-number profile of tumor specimen HCM-SANG-0307-C15-08A-01D-A80T-32 from HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 53d24e84-2b85-4901-a1dc-6c4668a12182.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0307-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/22a340e3-678a-40b5-95e4-828ddb6a895c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 943; copy number 1: 26,135; copy number 2: 30,764; copy number 3: 749; copy number 4: 51; copy number 5: 35; copy number 6: 93; copy number 7: 58; copy number 9: 16; copy number 10: 18; copy number 16: 32; copy number 42: 9; copy number 49: 8.

Homozygous deletions (total copy number 0; autosomes only): 430 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:82,340,771–82,340,876, 1 gene (within-gene range 0–1): RNU6-441P.
- chr10:87,863,625–88,049,823, 5 genes (within-gene range 0–1): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr14:68,236,243–68,422,196, 3 genes (within-gene range 0–1): RN7SL108P, AL122013.1, PPIAP6.
- chr15:20,128,745–22,373,570, 111 genes (broad region; genes not listed).
- chr21:34,787,801–36,637,033, 38 genes (within-gene range 0–6): RUNX1, AP000331.1, AF015262.1, RPL34P3, EZH2P1, AF015720.1, MIR802, RPS20P1, PPP1R2P2, LINC01436, RPL23AP3, SETD4, RIMKLBP1, SETD4-AS1, RNU6-992P, AP000688.1, CBR1, AP000688.3, AP000688.2, MEMO1P1, CBR3-AS1, RPS9P1, CBR3, DOP1B, RPL3P1, SRSF9P1, AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1, AP000695.1, AP000695.2, CLDN14, AP000695.3, PSMD4P1, AP000696.2, AP000696.1.
- chr21:37,337,382–46,691,226, 272 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:10,054,292–12,043,670, 66 genes, copy number 6 (broad region; genes not listed).
- chr8:12,310,962–12,388,296, 7 genes, copy number 7: DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr8:12,628,476–15,238,431, 35 genes, copy number 5–6 (within-gene range 2–11): RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1, SGCZ, AC022039.1, EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1.
- chr10:22,534,854–22,714,578, 2 genes, copy number 7: PIP4K2A, AL390318.1.
- chr12:24,223,233–27,824,382, 83 genes, copy number 9–49 (within-gene range 1–49) (broad region; genes not listed).
- chr17:52,862,121–52,987,652, 2 genes, copy number 6: LINC02089, LINC02876.
- chr17:58,755,854–58,985,179, 1 gene, copy number 7 (within-gene range 1–7): PPM1E.
- chr17:58,835,899–59,403,303, 23 genes, copy number 7: RNU6-518P, AC100832.1, Metazoa_SRP, AC100832.2, TRIM37, RN7SL716P, AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17, YPEL2, AC091059.2, MIR4729, AC091059.1.
- chr17:59,565,558–60,666,280, 46 genes, copy number 5–7: DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,810,165–60,811,462, 1 gene, copy number 5 (within-gene range 2–5): KRT18P61.
- chr17:64,506,865–64,662,307, 3 genes, copy number 5 (within-gene range 1–5): CEP95, SMURF2, AC009994.1.

Autosomal genes at a single copy (total copy number 1): 23,792. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
